Somatic mutation profile of tumor specimen TCGA-A3-3313-01A (aliquot TCGA-A3-3313-01A-01D-0966-08) from TCGA case TCGA-A3-3313, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.0 years (21,556 days).
Specimen TCGA-A3-3313-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 325e85a5-539c-4795-bedb-e45a0b6c4cf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3313-11A (Solid Tissue Normal), aliquot TCGA-A3-3313-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/864dcbab-66b3-4ff9-ada5-d445014a9da4

The open-access MAF lists 95 somatic variants for this specimen: 78 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 15, Frame Shift Del 7, Nonsense Mutation 5, Frame Shift Ins 5, RNA 1, Intron 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCPH1 | c.74C>G p.S25* | Nonsense Mutation (SNP) | VAF 66/204 reads (32%) | catalogued as rs121434305, CM021634; ClinVar: pathogenic; called by muse, mutect2
- ATP8A1 | c.367C>G p.R123G | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52530727; called by muse, mutect2, varscan2
- BUB1B | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV55009570; called by muse, mutect2, varscan2
- CDH7 | c.1975G>T p.G659* | Nonsense Mutation (SNP) | VAF 9/132 reads (7%) | catalogued as COSV59881280; called by muse, mutect2
- DDX60L | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV52714629; called by muse, mutect2, varscan2
- EPB41L3 | c.2829del p.K943Nfs*9 | Frame Shift Del (DEL) | VAF 55/173 reads (32%) | catalogued as rs1567966618; called by mutect2, pindel, varscan2
- HTR7 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519305; called by muse, mutect2
- KRT28 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 56/553 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs923265611; called by muse, mutect2, varscan2
- LRIG3 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.77); catalogued as COSV57862447; called by muse, mutect2
- MCM2 | c.2236A>T p.M746L | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1370918842; called by muse, mutect2, varscan2
- PKHD1 | c.8600C>T p.S2867F | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs765481635; called by muse, mutect2, varscan2
- PRKDC | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1456557309, COSV100038511; called by muse, mutect2, varscan2
- SLC9A8 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV64288379; called by muse, mutect2, varscan2
- TAF5 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1226366834; called by muse, mutect2
- TNFRSF11B | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs757952532; called by muse, mutect2, varscan2
- TTN | c.22733C>T p.P7578L (on ENST00000591111; = p.P6651L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | PolyPhen benign (0.015); catalogued as COSV60168543; called by muse, mutect2, varscan2
- UBR2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 514/841 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65768610; called by muse, mutect2, varscan2
- UTP11 | c.496T>A p.F166I | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV65951969; called by muse, mutect2
- ZFHX4 | c.2483A>G p.N828S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs1299909189; called by muse, mutect2, varscan2
- ZNF789 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs1171134141; called by muse, mutect2, varscan2
- AARS1 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ADAM11 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP32 | c.4906C>T p.Q1636* (on ENST00000310343 / NM_001378025.1; = p.Q1287* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- AVIL | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- C8A | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.307); called by muse, mutect2
- CACNA1G | c.3507G>T p.K1169N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CHST10 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- CTBP2 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CUL5 | c.816_817del p.F273* | Frame Shift Del (DEL) | VAF 36/301 reads (12%) | called by mutect2, pindel, varscan2
- DAPL1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- DIP2C | c.3974T>A p.L1325Q | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF1 | c.195+2T>C p.X65_splice | Splice Site (SNP) | VAF 75/162 reads (46%) | called by muse, mutect2, varscan2
- ENPP4 | c.980dup p.N327Kfs*2 | Frame Shift Ins (INS) | VAF 321/550 reads (58%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.517A>T p.I173F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ERICH6 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FAT4 | c.5635_5636insATTT p.I1879Nfs*5 | Frame Shift Ins (INS) | VAF 80/317 reads (25%) | called by mutect2, pindel, varscan2
- FOXRED2 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- GLIS2 | c.218_220dup p.F73dup | In Frame Ins (INS) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- GPR179 | c.5345C>A p.A1782D (on ENST00000621958; = p.A1781D on NM_001004334.4) | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- GRSF1 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 155/425 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GUSB | c.1703_1709del p.Q568Lfs*24 | Frame Shift Del (DEL) | VAF 70/175 reads (40%) | called by mutect2, pindel*, varscan2
- HSD17B2 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IQGAP3 | c.2811C>G p.D937E | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIF7 | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LARS2 | c.1529A>G p.K510R | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCPH1 | c.72T>A p.Y24* | Nonsense Mutation (SNP) | VAF 63/204 reads (31%) | called by muse, mutect2
- MPRIP | c.2052G>C p.E684D | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- MYCBP2 | c.2791C>A p.H931N (on ENST00000357337; = p.H969N on NM_015057.5) | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NUMA1 | c.364A>G p.K122E | Missense Mutation (SNP) | VAF 182/399 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OPA1 | c.2686_2689dup p.R897Ifs*2 (on ENST00000361510 / NM_130837.3; = p.R842Ifs*2 on NM_015560.3) | Frame Shift Ins (INS) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- PDIA6 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHA3 | c.614T>G p.M205R | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- POC1B | c.1305T>G p.I435M | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RICTOR | c.4568G>C p.C1523S | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF6 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RORA | c.390A>T p.L130F (on ENST00000335670 / NM_134261.3; = p.L155F on NM_002943.3) | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPS19 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- SAAL1 | c.201dup p.E68Rfs*5 | Frame Shift Ins (INS) | VAF 119/455 reads (26%) | called by mutect2, pindel, varscan2
- SEC14L1 | c.1790_1791dup p.V598Kfs*16 | Frame Shift Ins (INS) | VAF 159/611 reads (26%) | called by mutect2, pindel, varscan2
- SH2D2A | c.732G>C p.R244S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SLC12A8 | c.1766dup p.Y589* | Nonsense Mutation (INS) | VAF 42/125 reads (34%) | called by mutect2, pindel, varscan2
- SLIT1 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SNX14 | c.2603del p.K868Sfs*12 (on ENST00000314673 / NM_001350535.1; = p.K815Sfs*12 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 53/144 reads (37%) | called by mutect2, pindel, varscan2
- SYCE1 | c.389T>C p.L130S (on ENST00000343131 / NM_001143764.3; = p.L94S on NM_130784.3) | Missense Mutation (SNP) | VAF 198/792 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TACC2 | c.7573A>G p.I2525V (on ENST00000334433; = p.I603V on NM_006997.4) | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TCOF1 | c.3107G>T p.S1036I (on ENST00000377797 / NM_001135243.1; = p.S959I on NM_000356.4) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TENT2 | c.1285T>G p.Y429D | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMC5 | c.2114T>A p.I705N (on ENST00000396229 / NM_001105248.1; = p.I459N on NM_024780.5) | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TMEM131L | c.2620del p.T874Rfs*12 | Frame Shift Del (DEL) | VAF 130/430 reads (30%) | called by mutect2, pindel, varscan2
- TNNT2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- UBR2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 444/723 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.1320_1324del p.N440Kfs*8 | Frame Shift Del (DEL) | VAF 131/349 reads (38%) | called by mutect2, pindel, varscan2
- UNC13C | c.2805A>C p.L935F | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- USP24 | c.6754del p.Y2252Ifs*5 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- VARS2 | c.2160C>A p.F720L | Missense Mutation (SNP) | VAF 115/221 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- VRTN | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- WBP11 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 161/496 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF474 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- AAR2 | c.849G>T p.R283= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- ANGEL2 | c.1083T>C p.Y361= | Silent (SNP) | VAF 59/163 reads (36%) | called by muse, mutect2, varscan2
- C3orf38 | c.99C>T p.V33= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- KIAA1549 | c.1467T>C p.P489= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1202974185; called by muse, mutect2, varscan2
- KMT2C | c.14064C>A p.T4688= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- LDHAL6B | c.669T>A p.I223= | Silent (SNP) | VAF 61/189 reads (32%) | called by muse, mutect2, varscan2
- MTDH | c.1485T>C p.T495= | Silent (SNP) | VAF 100/272 reads (37%) | catalogued as rs1464198762, COSV100292745; called by muse, mutect2, varscan2
- NEU1 | c.384C>T p.V128= | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as COSV99999494; called by muse, mutect2, varscan2
- NWD1 | c.3522G>A p.V1174= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs1206379273; called by muse, mutect2, varscan2
- PIDD1 | c.150G>A p.L50= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- PSD3 | c.1527A>C p.A509= | Silent (SNP) | VAF 142/356 reads (40%) | called by muse, mutect2, varscan2
- TRPC4 | c.30T>G p.V10= | Silent (SNP) | VAF 106/274 reads (39%) | called by muse, mutect2, varscan2
- TSNAX | c.555C>A p.V185= | Silent (SNP) | VAF 200/536 reads (37%) | called by muse, varscan2
- VARS2 | c.2217C>T p.V739= | Silent (SNP) | VAF 107/216 reads (50%) | called by muse, mutect2, varscan2
- ZNF484 | c.465T>C p.Y155= | Silent (SNP) | VAF 170/469 reads (36%) | called by muse, mutect2, varscan2
- SH2D6 | n.433G>A | RNA (SNP) | VAF 20/65 reads (31%) | catalogued as rs747754782; called by muse, mutect2, varscan2
- TIPIN | c.475+1791G>A | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2, varscan2
